Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3553, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3553-01A (Primary Tumor).

Diagnosis:

Resected colon with a moderately differentiated adenocarcinoma of colorectal type measuring max 3.5cm with infiltration to the tunica muscularis propria. Tumor-free lymph nodes in this region.

Tumor-free colonic resection margins. Tumor-free mesenteric resection margin.

Tumor stage therefore pT2, pN0 (0/21) pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file e676857a-5a1e-4ddb-a13c-39df53db8a24 (TCGA-AA-3553.B7A765AE-6321-4F5E-8894-7B23B6C39BD6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).